Somatic mutation profile of tumor specimen TARGET-10-PARCVB-09A (aliquot TARGET-10-PARCVB-09A-01D) from TARGET case TARGET-10-PARCVB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (979 days).
Specimen TARGET-10-PARCVB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5335d9bf-3aa1-429a-975b-9da42585a15d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCVB-10A (Blood Derived Normal), aliquot TARGET-10-PARCVB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2ec2930-22fb-4088-a311-678823e5e902

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA5 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143154450; called by muse, mutect2, varscan2
- JAK1 | c.1972G>C p.V658L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61086927, COSV61091213; called by muse, mutect2, varscan2
- LRRC53 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs545759786; called by muse, mutect2, varscan2
- OR51D1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99052256; called by muse, mutect2
- SOD3 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV66125507; called by muse, mutect2, varscan2
- GOLGA1 | c.2268_2271dup p.S758Afs*24 | Frame Shift Ins (INS) | VAF 23/74 reads (31%) | called by mutect2, varscan2
- LPAR4 | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MYO9A | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NKD1 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PAX5 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- PCDH7 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTP5 | c.141G>A p.L47= | Silent (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.718-370_718-368del | Intron (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- GPR32P1 | n.499C>T | RNA (SNP) | VAF 28/53 reads (53%) | catalogued as rs577722342; called by muse, mutect2, varscan2
- LGR5 | c.*119G>C | 3'UTR (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- ZNF33A | chr10:38064421 C>T | 3'Flank (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
